Surgical pathology report (de-identified scan), TCGA case TCGA-44-7662, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7662-01A (Primary Tumor).

[page 1 of 2]
Procedure: [REDACTED]

Diagnosis

- A. Lung, left upper lobe, lobectomy:
Adenocarcinoma, poorly differentiated
2.8 cm, involving the lobar bronchus (pT2a)
Bronchial and vascular resection margins negative for malignancy
Pleural surface negative for malignancy
2 bronchial lymph nodes negative for malignancy (0/2)
- B. Lymph node, level X, biopsy:
One lymph node negative for malignancy (0/1)
- C. Lymph node, level V, biopsy:
One lymph node negative for malignancy (0/1)
- D. Lymph node, level VII, biopsy:
One lymph node negative for malignancy (0/1)

Microscopic Description:

A-D Microscopic examination performed.
Histologic type: Adenocarcinoma, tumor cells stain strongly positive for cytokeratin 7 and TT F1 and have focal mucicarmine positive intracytoplasmic vacuoles. The tumor cells were completely negative for CK 5/6 and showed less than 50% moderate staining with p63
Histologic grade: Poorly differentiated
Primary tumor (pT): Tumor is 2.8 cm (pT2a)
Margins of resection: Negative for tumor
Direct extension of tumor: Tumor involves the lobar bronchus, the mainstem left bronchus was not submitted of the specimen. The tumor invades the pulmonary parenchyma. The pleural surface is negative
Venous (large vessel) invasion: Not identified
Arterial (large vessel) invasion: Not identified
Lymphatic (small vessel) invasion: Not identified
Regional lymph nodes (pN): A total of 5 lymph nodes were evaluated and were all negative for tumor (pN0)
Distant metastasis (pM): [Not evaluated (pMX)]
Other findings: Focal pulmonary hemorrhage compatible with procedural effects. Marked background anthracosis and emphysema.

Specimen

- A. Left upper lobe
B. Level X lymph node
C. Level V lymph node
D. Level VII lymph node

Clinical Information

Lung nodule

[page 2 of 2]
Gross Description

A. Received fresh labeled "left upper lobe" is a 291 Gram, 23.5 x 13.5 x 4.0 cm specimen with attached 1.2 cm in length, 2.1 x 0.5 cm bronchial stump. The pleura is smooth to scabrous tan-pink-red. There is a moderately well circumscribed, and 2.8 x 2.5 x 2.0 cm rubbery tan-white lesions adjacent to the bronchial stump. The pleura adjacent to the lesion along the hilar surface is inked orange. On sectioning the tumor is tan-white to gray-black and extends to within 1.3 cm of the inked surface (see blocks 3 through 5). A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The remaining parenchyma is uniform tan red with a spongiform consistency. No additional mass lesion is identified. 2 slightly rubbery tan-pink-red tissues in keeping with lymph nodes measuring up to 0.7 cm are recovered from the hilum.

10.

Summary: 1 - bronchial margin en face; 2 - vascular margins; 3 through 5 - tumor to inked pleural surface at region of hilum; 6 and 7 - tumor adjacent parenchyma; 8 and 9 - random parenchyma; 10 - 2 lymph nodes

B. Received fresh labeled "level X lymph node" is a 1.3 x 1.0 x 0.7 cm tan-red lymph node tissue which is bisected and entirely submitted in one block.

C. Received in formalin labeled "level V" is a 1.5 x 1 x 0.6 CM and black tissue consistent with lymph node is bisected and entirely submitted one block

D. Received in formalin labeled "level VII node" are 2 pieces of tan tissue measuring 1 x 0.6 x 0.2 CM entirely submitted one block

Source: NCI Genomic Data Commons file d3541170-f0f2-4550-a69a-c641a75bcc91 (TCGA-44-7662.7B34E153-7BC5-4BA6-8445-BAC63CA2DCC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).